Somatic mutation profile of tumor specimen C3N-02330-03 (aliquot CPT0135580009) from CPTAC case C3N-02330, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 51.3 years (18,726 days).
Specimen C3N-02330-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3aea3264-683c-40f0-b401-655f09af136c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02330-72 (Blood Derived Normal), aliquot CPT0135690002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69bc2444-4ab8-4a7c-aceb-5f3d607993a9

The open-access MAF lists 447 somatic variants for this specimen: 276 protein-altering or splice-affecting, 164 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 251, Silent 164, Nonsense Mutation 11, Splice Region 5, Intron 5, Splice Site 4, 5'Flank 2, Frame Shift Del 2, In Frame Ins 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A1CF | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 71/335 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); catalogued as rs746131925; called by muse, mutect2, varscan2
- A1CF | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 45/257 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV50957343, COSV51028098; called by muse, mutect2, varscan2
- ABCC2 | c.2933C>T p.S978L | Missense Mutation (SNP) | VAF 68/390 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs763988128, COSV64984835; called by muse, mutect2, varscan2
- AC008397.2 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 53/349 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as rs369793065; called by muse, mutect2, varscan2
- ADAM11 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 68/375 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV52349480; called by muse, mutect2, varscan2
- ADAM18 | c.1852C>T p.H618Y | Missense Mutation (SNP) | VAF 47/250 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.296); catalogued as rs866076661, COSV55845988; called by muse, varscan2
- ADAMTS9 | c.3253C>T p.R1085* | Nonsense Mutation (SNP) | VAF 62/373 reads (17%) | catalogued as COSV55781645; called by muse, mutect2, varscan2
- ADGRB3 | c.2061G>A p.M687I | Missense Mutation (SNP) | VAF 31/244 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as rs1470554633; called by muse, mutect2, varscan2
- ADGRL3 | c.1283C>T p.S428L (on ENST00000506720 / NM_001322402.2; = p.S360L on NM_015236.6) | Missense Mutation (SNP) | VAF 77/445 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as COSV101547105, COSV72265283; called by muse, mutect2, varscan2
- AKR1C2 | c.84+1G>A p.X28_splice | Splice Site (SNP) | VAF 31/235 reads (13%) | catalogued as rs781949902; called by muse, mutect2, varscan2
- AKR7A2 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 52/327 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as rs201888607; called by muse, mutect2, varscan2
- ANTKMT | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 106/619 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as rs757564119, COSV53497976; called by muse, mutect2, varscan2
- APBB1 | c.1604C>T p.P535L | Missense Mutation (SNP) | VAF 32/290 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773670333; called by muse, mutect2, varscan2
- AQR | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 49/323 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV50029552; called by muse, mutect2, varscan2
- ARMC4 | c.2299G>A p.D767N | Missense Mutation (SNP) | VAF 56/387 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV59471571; called by muse, mutect2, varscan2
- BACH1 | c.1813C>T p.H605Y | Missense Mutation (SNP) | VAF 47/323 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as COSV54519123; called by muse, mutect2, varscan2
- BDKRB2 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 74/489 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.132); catalogued as rs201521050; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1279C>T p.L427F | Missense Mutation (SNP) | VAF 68/365 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as rs781014438; called by muse, mutect2, varscan2
- C4B | c.3752C>T p.S1251F | Missense Mutation (SNP) | VAF 84/824 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as rs1192847595; called by muse, mutect2
- CCT2 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 47/270 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as rs747101634; called by muse, mutect2, varscan2
- CD3G | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 57/359 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.357); catalogued as rs1483357286; called by muse, mutect2, varscan2
- CFAP251 | c.3025G>A p.E1009K | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs776727712, COSV56608786; called by muse, mutect2, varscan2
- CLDN18 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 65/448 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1054052863; called by muse, mutect2, varscan2
- CLEC14A | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 104/687 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.988); catalogued as rs1319502188; called by muse, mutect2, varscan2
- CNGA3 | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 47/296 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.053); catalogued as rs1313549731; called by muse, mutect2, varscan2
- CNTN1 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 34/258 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61636194; called by muse, mutect2, varscan2
- CNTNAP5 | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 84/436 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.146); catalogued as rs765295281, COSV70502693; called by muse, mutect2, varscan2
- CRABP1 | c.314G>A p.G105D | Missense Mutation (SNP) | VAF 70/485 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55115376, COSV55115833; called by muse, mutect2, varscan2
- CRTAC1 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 59/352 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV54004899; called by muse, mutect2, varscan2
- DDX56 | c.25T>A p.F9I | Missense Mutation (SNP) | VAF 54/322 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV51837678; called by muse, mutect2, varscan2
- DNAH11 | c.10511A>G p.K3504R | Missense Mutation (SNP) | VAF 64/451 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100181333, COSV60973213; called by muse, mutect2, varscan2
- DNAH7 | c.4551G>A p.L1517= | Splice Region (SNP) | VAF 16/98 reads (16%) | catalogued as rs1330804631; called by mutect2, varscan2
- DNAH8 | c.12191G>A p.R4064Q | Missense Mutation (SNP) | VAF 48/329 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1327466194, COSV59421605; called by muse, mutect2, varscan2
- DOP1B | c.3220G>A p.E1074K | Missense Mutation (SNP) | VAF 73/451 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.218); catalogued as rs543294572; called by muse, mutect2, varscan2
- DPEP2NB | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 72/348 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.999); catalogued as rs537203014; called by muse, mutect2, varscan2
- DPP3 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 57/285 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.493); catalogued as COSV64756679; called by muse, mutect2, varscan2
- DTNB | c.649C>G p.P217A | Missense Mutation (SNP) | VAF 41/307 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs368967650; called by muse, mutect2, varscan2
- EML1 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.241); catalogued as rs758842019, COSV51744667; called by muse, mutect2, varscan2
- EPN1 | c.691C>T p.R231C (on ENST00000270460 / NM_001321263.1; = p.R206C on NM_013333.3) | Missense Mutation (SNP) | VAF 46/446 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs773651149, COSV99322417; called by muse, mutect2, varscan2
- ERICH3 | c.1549G>A p.G517R | Missense Mutation (SNP) | VAF 53/311 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.799); catalogued as rs1483052645, COSV104399631; called by muse, mutect2, varscan2
- FAT1 | c.9385C>T p.P3129S | Missense Mutation (SNP) | VAF 84/468 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.424); catalogued as COSV71673549; called by muse, mutect2
- FBXW9 | c.946G>A p.G316S (on ENST00000587955; = p.G296S on NM_032301.3) | Missense Mutation (SNP) | VAF 91/589 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs372031100, COSV100982035; called by muse, mutect2, varscan2
- FLNC | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 488/878 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as rs758342140, COSV57954318; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- G0S2 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 192/420 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.204); catalogued as COSV65433098, COSV65433118; called by muse, mutect2, varscan2
- GATA3 | c.917G>C p.R306T | Missense Mutation (SNP) | VAF 44/263 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV60522371; called by muse, mutect2, varscan2
- GLB1L3 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 53/378 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV68393476; called by muse, mutect2, varscan2
- GLIPR1L2 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 61/316 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1415887333; called by muse, mutect2, varscan2
- GLIS1 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 103/560 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs774353930; called by muse, mutect2, varscan2
- GSDMC | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 65/423 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs375510820; called by muse, mutect2, varscan2
- HBB | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 45/337 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.295); catalogued as CM055962, CM940916; called by muse, mutect2, varscan2
- HGFAC | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 81/421 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV66976761; called by muse, mutect2, varscan2
- HLA-DOA | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 196/559 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs769161861, COSV57713518, COSV57714983, COSV57715838; called by muse, mutect2, varscan2
- IGHG3 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 63/383 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776233152; called by muse, mutect2, varscan2
- IGKV1-8 | c.281C>T p.T94I | Missense Mutation (SNP) | VAF 78/391 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as rs751038571; called by muse, mutect2, varscan2
- IGSF10 | c.5272C>T p.H1758Y | Missense Mutation (SNP) | VAF 62/410 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as COSV56791613; called by muse, mutect2, varscan2
- IQCM | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 44/314 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.143); catalogued as rs1365816897; called by muse, mutect2, varscan2
- ITGAL | c.3130G>A p.E1044K | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs199892523; called by muse, mutect2, varscan2
- ITGB7 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 70/456 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV57238877; called by muse, mutect2, varscan2
- ITGB8 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 44/232 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs267601448, COSV56004613; called by muse, mutect2, varscan2
- KCNT2 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 169/423 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.743); catalogued as COSV54111948; called by muse, mutect2, varscan2
- LIPF | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs138641581; called by muse, mutect2, varscan2
- LITAFD | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 32/242 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1265780328; called by muse, mutect2, varscan2
- LSR | c.1538C>T p.P513L (on ENST00000361790; = p.P494L on NM_015925.6) | Missense Mutation (SNP) | VAF 106/572 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs543146732; called by muse, mutect2, varscan2
- MAGEB4 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 100/528 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs370810015, COSV100975088, COSV66776750; called by muse, mutect2, varscan2
- MEOX1 | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 68/413 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs888575087, COSV59355496, COSV59356802; called by muse, mutect2, varscan2
- MGAM2 | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 240/447 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs957006911; called by muse, mutect2, varscan2
- MYH4 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 56/342 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55123889; called by muse, mutect2, varscan2
- MYO1G | c.2457G>A p.M819I | Missense Mutation (SNP) | VAF 110/719 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.222); catalogued as COSV99348404; called by muse, mutect2, varscan2
- NCS1 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 56/325 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64962575; called by muse, mutect2, varscan2
- NEBL | c.2452G>A p.D818N | Missense Mutation (SNP) | VAF 67/406 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs1457665218, COSV65804785; called by muse, mutect2, varscan2
- NLRP8 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 40/301 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as COSV52583981; called by muse, mutect2, varscan2
- NPY1R | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 71/465 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1437014906; called by muse, mutect2, varscan2
- OR14C36 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 303/570 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs772942807, COSV58600556, COSV58602844; called by muse, mutect2, varscan2
- OR4K17 | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 69/340 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs780993428, COSV59648742, COSV59649214; called by muse, mutect2, varscan2
- OR4N2 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 50/356 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60050301; called by muse, mutect2
- OR5B12 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 59/399 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV56903931; called by muse, mutect2, varscan2
- OR5H2 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 74/408 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV62350202; called by muse, mutect2, varscan2
- OR5M8 | c.304C>T p.L102F | Missense Mutation (SNP) | VAF 95/481 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765641462, COSV59118159; called by muse, mutect2, varscan2
- OR6C74 | c.136C>T p.L46F | Missense Mutation (SNP) | VAF 56/408 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); catalogued as COSV59606938; called by muse, mutect2, varscan2
- OTOP3 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 45/236 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as rs867239064, COSV60912216; called by muse, mutect2, varscan2
- PAXIP1 | c.3077del p.L1026* | Frame Shift Del (DEL) | VAF 203/466 reads (44%) | catalogued as COSV66898612; called by mutect2, pindel, varscan2
- PCDH18 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 76/433 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV61266223; called by muse, mutect2, varscan2
- PIK3C2G | c.3601G>A p.E1201K (on ENST00000676171; = p.E1160K on NM_004570.5) | Missense Mutation (SNP) | VAF 44/263 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV56796183; called by muse, mutect2, varscan2
- PPY | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 94/488 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as rs555231892, COSV99078838; called by muse, mutect2, varscan2
- PREX2 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 34/219 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs773476490, COSV55758076; called by muse, mutect2
- PRICKLE2 | c.514G>A p.G172R (on ENST00000295902; = p.G116R on NM_198859.4) | Missense Mutation (SNP) | VAF 75/446 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99897529; called by muse, mutect2, varscan2
- PSMD3 | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 53/310 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV52856506; called by muse, mutect2, varscan2
- RBPJL | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 72/417 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762532634, COSV59216121; called by muse, mutect2, varscan2
- RCOR2 | c.1037G>A p.R346K | Missense Mutation (SNP) | VAF 45/285 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs1411039482; called by muse, mutect2, varscan2
- RELN | c.3061G>A p.E1021K | Missense Mutation (SNP) | VAF 336/626 reads (54%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.955); catalogued as rs910972681, COSV58986974; called by muse, mutect2, varscan2
- REPS1 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 51/314 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57812453; called by muse, mutect2, varscan2
- RPTOR | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 51/342 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV60806614; called by muse, mutect2, varscan2
- RTP5 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 131/744 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.703); catalogued as COSV100574766; called by muse, mutect2, varscan2
- SCARB2 | c.667C>T p.L223F | Missense Mutation (SNP) | VAF 23/219 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1472142413; called by muse, mutect2, varscan2
- SGSM1 | c.1388G>A p.G463E | Missense Mutation (SNP) | VAF 105/548 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV68514199; called by muse, mutect2, varscan2
- SH3GL3 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 81/464 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs149232982; called by muse, mutect2, varscan2
- SI | c.4549G>A p.E1517K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52282947; called by muse, mutect2, varscan2
- SI | c.3127G>A p.E1043K | Missense Mutation (SNP) | VAF 51/309 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52275009; called by muse, mutect2, varscan2
- SLC5A8 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 51/383 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs767362595, COSV73310712; called by muse, mutect2, varscan2
- SP110 | c.2032C>T p.H678Y | Missense Mutation (SNP) | VAF 42/300 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.158); catalogued as rs866076768; called by muse, mutect2, varscan2
- SPANXN1 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 46/337 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as rs201529247, COSV100979251; called by muse, mutect2, varscan2
- SPHKAP | c.4625G>A p.R1542Q | Missense Mutation (SNP) | VAF 51/259 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs368367152, COSV60881066; called by muse, mutect2, varscan2
- SPHKAP | c.1577C>T p.S526L | Missense Mutation (SNP) | VAF 69/435 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs760510406, COSV60893705; called by muse, mutect2, varscan2
- SPOCK1 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 46/338 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99968233; called by muse, mutect2, varscan2
- ST18 | c.2098C>T p.P700S | Missense Mutation (SNP) | VAF 46/330 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV52507679; called by muse, mutect2, varscan2
- STAB2 | c.6155C>T p.T2052M | Missense Mutation (SNP) | VAF 45/263 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.077); catalogued as rs148460946, COSV66342876; called by muse, mutect2, varscan2
- STIL | c.3491T>C p.L1164P | Missense Mutation (SNP) | VAF 65/457 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs780930663; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SUPT16H | c.2002C>T p.R668C | Missense Mutation (SNP) | VAF 52/344 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV53524330, COSV53524666; called by muse, mutect2, varscan2
- TENM3 | c.3148C>T p.P1050S | Missense Mutation (SNP) | VAF 71/410 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as rs1160806863; called by muse, mutect2, varscan2
- TMEM240 | c.313G>A p.V105M | Missense Mutation (SNP) | VAF 96/474 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.466); catalogued as rs373327807; called by muse, mutect2, varscan2
- TMEM270 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 438/830 reads (53%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs782138484; called by muse, mutect2, varscan2
- TOX3 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 68/422 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV99568236; called by muse, mutect2, varscan2
- TRANK1 | c.4583G>A p.R1528K | Missense Mutation (SNP) | VAF 76/368 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV57145807; called by muse, mutect2, varscan2
- TRAV24 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 72/319 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as rs373850474; called by muse, mutect2, varscan2
- TRMT2B | c.1168+1G>A p.X390_splice | Splice Site (SNP) | VAF 63/322 reads (20%) | catalogued as COSV100105212; called by muse, mutect2, varscan2
- TRPC3 | c.2701G>A p.E901K (on ENST00000379645 / NM_001366479.2; = p.E828K on NM_003305.2) | Missense Mutation (SNP) | VAF 53/354 reads (15%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.013); catalogued as rs200028855, COSV53372750, COSV53376421; called by muse, mutect2, varscan2
- TTC6 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 69/343 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.718); catalogued as rs1333878713, COSV73285863; called by muse, mutect2, varscan2
- TTN | c.74069G>A p.R24690Q (on ENST00000591111; = p.R17266Q on NM_003319.4) | Missense Mutation (SNP) | VAF 81/437 reads (19%) | PolyPhen probably damaging (0.996); catalogued as rs758190406, COSV60188912; called by muse, mutect2, varscan2
- UBR4 | c.13327C>T p.R4443C | Missense Mutation (SNP) | VAF 39/312 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100920967; called by muse, mutect2, varscan2
- UGT8 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 78/472 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as rs1560676395; called by muse, mutect2, varscan2
- USH1C | c.1080G>A p.M360I | Missense Mutation (SNP) | VAF 48/264 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV50014609; called by muse, mutect2, varscan2
- VPS13C | c.8312C>T p.P2771L (on ENST00000644861 / NM_020821.3; = p.P2728L on NM_017684.5) | Missense Mutation (SNP) | VAF 79/451 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1566997925; called by muse, mutect2, varscan2
- WDR72 | c.2660G>A p.G887E | Missense Mutation (SNP) | VAF 47/257 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV64743570; called by muse, mutect2, varscan2
- WDR76 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 54/350 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs140699198; called by muse, mutect2, varscan2
- ZCCHC18 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 64/433 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs1454671614, COSV62461278; called by muse, varscan2
- ZFP82 | c.1187G>A p.C396Y | Missense Mutation (SNP) | VAF 87/495 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776649945, COSV67565183; called by muse, mutect2, varscan2
- ZKSCAN3 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 111/433 reads (26%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.522); catalogued as rs149631927; called by muse, mutect2, varscan2
- ZNF385B | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 93/581 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs897681323, COSV101343153; called by muse, mutect2, varscan2
- ZNF787 | c.1034C>T p.S345L | Missense Mutation (SNP) | VAF 96/553 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs780933938, COSV54420329; called by muse, mutect2, varscan2
- ACSM2B | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 63/337 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- ACTL9 | c.30A>C p.E10D | Missense Mutation (SNP) | VAF 95/467 reads (20%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.009); called by mutect2, varscan2
- ADAMTS10 | c.1987C>T p.P663S | Missense Mutation (SNP) | VAF 65/460 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- ADCY7 | c.348G>A p.W116* | Nonsense Mutation (SNP) | VAF 66/409 reads (16%) | called by muse, mutect2, varscan2
- AEBP1 | c.1486-3C>T | Splice Region (SNP) | VAF 104/658 reads (16%) | called by muse, mutect2, varscan2
- AIFM3 | c.314T>A p.L105Q | Missense Mutation (SNP) | VAF 52/371 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- AKAP6 | c.6910G>A p.E2304K | Missense Mutation (SNP) | VAF 53/323 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- AKR1C2 | c.84G>A p.E28= | Splice Region (SNP) | VAF 31/238 reads (13%) | called by muse, mutect2, varscan2
- AKR7A2 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 54/330 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- ALG11 | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 80/392 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ALOX12 | c.623G>A p.W208* | Nonsense Mutation (SNP) | VAF 62/369 reads (17%) | called by muse, mutect2, varscan2
- ALOX12 | c.624G>A p.W208* | Nonsense Mutation (SNP) | VAF 61/365 reads (17%) | called by muse, mutect2, varscan2
- ANGPT4 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 44/283 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- ANKDD1A | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 56/288 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARMCX5 | c.33A>T p.R11S | Missense Mutation (SNP) | VAF 80/518 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.404C>T p.T135I | Missense Mutation (SNP) | VAF 106/553 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ASAH2 | c.1416G>A p.G472= | Splice Region (SNP) | VAF 44/291 reads (15%) | called by muse, mutect2, varscan2
- ATF4 | c.433C>A p.P145T | Missense Mutation (SNP) | VAF 67/419 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATF4 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 64/422 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BARX2 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 80/500 reads (16%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRAF | c.1629_1637dup p.V544_R546dup (on ENST00000288602 / NM_001374244.1; = p.V504_R506dup on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Ins (INS) | VAF 127/274 reads (46%) | called by mutect2, varscan2
- BTN3A2 | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 71/1277 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); called by muse, mutect2
- CABLES2 | c.713A>T p.K238M | Missense Mutation (SNP) | VAF 44/270 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CCDC120 | c.494G>A p.R165K | Missense Mutation (SNP) | VAF 124/653 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH12 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 81/433 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CHRNA3 | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 95/544 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHST10 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 41/290 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- CLMN | c.2770G>A p.D924N | Missense Mutation (SNP) | VAF 44/273 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CLVS2 | c.512A>G p.Q171R | Missense Mutation (SNP) | VAF 72/433 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- CNTN6 | c.2860G>A p.E954K | Missense Mutation (SNP) | VAF 33/277 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CNTNAP4 | c.667C>T p.H223Y | Missense Mutation (SNP) | VAF 57/447 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- COL11A1 | c.2434C>T p.P812S | Missense Mutation (SNP) | VAF 65/431 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL13A1 | c.295-1G>A p.X99_splice | Splice Site (SNP) | VAF 30/233 reads (13%) | called by muse, mutect2, varscan2
- COL7A1 | c.6520G>A p.G2174S | Missense Mutation (SNP) | VAF 82/493 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CPLANE1 | c.8467C>T p.P2823S | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPLX2 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 69/440 reads (16%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.822); called by muse, varscan2
- CPNE4 | c.1169G>A p.G390E | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- CSF3R | c.1343G>A p.G448D | Missense Mutation (SNP) | VAF 94/616 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSPP1 | c.745C>T p.P249S (on ENST00000676605; = p.P208S on NM_024790.6) | Missense Mutation (SNP) | VAF 51/305 reads (17%) | SIFT tolerated (0.94); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CSTL1 | c.375C>A p.N125K | Missense Mutation (SNP) | VAF 47/299 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by mutect2, varscan2
- CTPS2 | c.580dup p.T194Nfs*30 | Frame Shift Ins (INS) | VAF 52/368 reads (14%) | called by mutect2, pindel, varscan2
- CUL3 | c.887T>C p.L296P | Missense Mutation (SNP) | VAF 49/299 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYP2A13 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 89/617 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- CYP2B6 | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 91/519 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- DDHD1 | c.1541C>T p.S514L (on ENST00000323669; = p.S711L on NM_030637.3) | Missense Mutation (SNP) | VAF 82/515 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- DMXL1 | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 30/221 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH12 | c.1928G>A p.R643K | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DOCK10 | c.6452G>A p.G2151D | Missense Mutation (SNP) | VAF 46/292 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOCK11 | c.5875C>T p.P1959S | Missense Mutation (SNP) | VAF 46/295 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF4H | c.479A>G p.D160G | Missense Mutation (SNP) | VAF 361/644 reads (56%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- EOMES | c.1193C>A p.P398H | Missense Mutation (SNP) | VAF 48/356 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPG5 | c.1546C>T p.L516F | Missense Mutation (SNP) | VAF 62/297 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERICH3 | c.3739G>A p.D1247N | Missense Mutation (SNP) | VAF 93/561 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- FAM151A | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 60/376 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT1 | c.5783C>T p.S1928F | Missense Mutation (SNP) | VAF 86/451 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FOXP1 | c.1967A>G p.N656S | Missense Mutation (SNP) | VAF 69/421 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- G0S2 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 184/413 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- GALNTL6 | c.1103G>A p.R368K | Missense Mutation (SNP) | VAF 60/341 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GLI1 | c.2302C>T p.Q768* | Nonsense Mutation (SNP) | VAF 100/517 reads (19%) | called by muse, mutect2, varscan2
- GPRASP2 | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 22/708 reads (3%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.481); called by muse, mutect2
- HAS2 | c.1529C>G p.T510R | Missense Mutation (SNP) | VAF 65/373 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- HIRA | c.1387C>T p.P463S | Missense Mutation (SNP) | VAF 56/273 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGSF3 | c.2408C>T p.S803F (on ENST00000369486 / NM_001007237.3; = p.S823F on NM_001542.4) | Missense Mutation (SNP) | VAF 41/288 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ITGA5 | c.1210C>T p.Q404* | Nonsense Mutation (SNP) | VAF 59/315 reads (19%) | called by muse, mutect2, varscan2
- ITGA7 | c.1228G>C p.A410P (on ENST00000555728; = p.A366P on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 107/613 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KBTBD11 | c.1640C>T p.P547L | Missense Mutation (SNP) | VAF 134/681 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIAA1549L | c.2070C>G p.N690K (on ENST00000321505; = p.N987K on NM_012194.3) | Missense Mutation (SNP) | VAF 66/464 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); called by mutect2, varscan2
- KIF13A | c.467_476del p.K156Ifs*3 | Frame Shift Del (DEL) | VAF 37/286 reads (13%) | called by mutect2, pindel, varscan2
- KIR3DL2 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KISS1R | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 50/435 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.017); called by mutect2, varscan2
- KLK2 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KRT18 | c.701C>T p.T234I | Missense Mutation (SNP) | VAF 59/333 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LAS1L | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 87/531 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LCT | c.3040C>T p.P1014S | Missense Mutation (SNP) | VAF 62/429 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LEMD3 | c.2698C>T p.L900F | Missense Mutation (SNP) | VAF 60/362 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- LGALS13 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 51/247 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- LILRA1 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 32/302 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- LINGO4 | c.635G>A p.R212K | Missense Mutation (SNP) | VAF 236/583 reads (40%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- LMOD3 | c.512G>A p.R171K | Missense Mutation (SNP) | VAF 82/536 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP1B | c.1258A>G p.T420A | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRC9 | c.2686G>A p.G896R | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- MAP7 | c.2194G>T p.G732W | Missense Mutation (SNP) | VAF 48/369 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MED12L | c.3907G>A p.G1303R | Missense Mutation (SNP) | VAF 49/361 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- MKLN1 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 169/329 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- MUC2 | c.2531A>G p.N844S | Missense Mutation (SNP) | VAF 82/446 reads (18%) | SIFT tolerated (0.12); called by muse, mutect2, varscan2
- MYH14 | c.1522C>T p.H508Y | Missense Mutation (SNP) | VAF 78/452 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYO3B | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 55/390 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAP1L2 | c.307A>T p.S103C | Missense Mutation (SNP) | VAF 24/420 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- NDUFB11 | c.87G>A p.W29* | Nonsense Mutation (SNP) | VAF 112/606 reads (18%) | called by muse, mutect2, varscan2
- NLRC3 | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 100/592 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- OAT | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 43/333 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- OR10A7 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 91/472 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- OR13C5 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 92/371 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- OR2T6 | c.514C>T p.H172Y | Missense Mutation (SNP) | VAF 535/1022 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- OR8J2 | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 60/354 reads (17%) | called by muse, mutect2, varscan2
- OSBPL8 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 57/292 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- P2RY8 | c.901C>T p.Q301* | Nonsense Mutation (SNP) | VAF 102/500 reads (20%) | called by muse, varscan2
- PAQR5 | c.978T>G p.H326Q | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDE1C | c.1385G>A p.G462E | Missense Mutation (SNP) | VAF 60/319 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- PDZD8 | c.2613T>G p.F871L | Missense Mutation (SNP) | VAF 57/385 reads (15%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKD2 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 57/326 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PKHD1L1 | c.3221C>T p.P1074L | Missense Mutation (SNP) | VAF 44/284 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PLAAT1 | c.757G>A p.A253T (on ENST00000650797; = p.A148T on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/319 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PLEKHA6 | c.1945C>T p.Q649* | Nonsense Mutation (SNP) | VAF 160/364 reads (44%) | called by muse, mutect2, varscan2
- PLXNA2 | c.2762C>T p.A921V | Missense Mutation (SNP) | VAF 153/388 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); called by muse, varscan2
- POLK | c.1607G>A p.G536E | Missense Mutation (SNP) | VAF 45/304 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- POTEA | c.1030G>A p.E344K (on ENST00000519951 / NM_001005365.2; = p.E298K on NM_001002920.1) | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- POTED | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 67/376 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- POU2F3 | c.553C>A p.P185T | Missense Mutation (SNP) | VAF 64/476 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by mutect2, varscan2
- PPFIA3 | c.2835G>A p.Q945= | Splice Region (SNP) | VAF 72/436 reads (17%) | called by muse, mutect2, varscan2
- PRDM11 | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 64/367 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PRKAR1B | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 20/646 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2
- PRR35 | c.592T>C p.F198L | Missense Mutation (SNP) | VAF 100/522 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTCHD1 | c.1757C>T p.S586F | Missense Mutation (SNP) | VAF 94/501 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- PTPRQ | c.4552G>A p.E1518K (on ENST00000616559; = p.E1476K on NM_001145026.2) | Missense Mutation (SNP) | VAF 55/375 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- RAD54L2 | c.3383C>T p.P1128L | Missense Mutation (SNP) | VAF 55/396 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAI2 | c.1275A>C p.E425D | Missense Mutation (SNP) | VAF 135/730 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- RP1 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 45/300 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- RPL34 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 55/251 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- RSPO1 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 108/585 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- RYR3 | c.14359G>A p.E4787K (on ENST00000389232; = p.E4788K on NM_001036.6) | Missense Mutation (SNP) | VAF 51/251 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SCCPDH | c.770G>A p.R257K | Missense Mutation (SNP) | VAF 22/524 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- SERPING1 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 90/507 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SIGLEC1 | c.2288C>T p.P763L | Missense Mutation (SNP) | VAF 106/546 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- SLC18B1 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 41/248 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- SLC25A52 | c.160_162del p.N54del (on ENST00000672005; = p.N44del on NM_001034172.4) | In Frame Del (DEL) | VAF 62/352 reads (18%) | called by pindel, varscan2
- SLC27A6 | c.1580C>T p.S527F | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- SLC39A4 | c.1930G>A p.D644N (on ENST00000301305 / NM_001374839.1; = p.D619N on NM_017767.3) | Missense Mutation (SNP) | VAF 49/307 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMC3 | c.2848C>T p.P950S | Missense Mutation (SNP) | VAF 74/392 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMCHD1 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 42/265 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SNCAIP | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 77/378 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- TEX13B | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 85/672 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- TEX13D | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 63/417 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- TLL1 | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 51/242 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- TPTE | c.787C>T p.P263S (on ENST00000618007 / NM_199261.4; = p.P245S on NM_199259.4) | Missense Mutation (SNP) | VAF 30/678 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2
- TTC6 | c.2470G>A p.E824K | Missense Mutation (SNP) | VAF 60/271 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TTN | c.38107G>A p.E12703K (on ENST00000591111; = p.E5279K on NM_003319.4) | Missense Mutation (SNP) | VAF 60/393 reads (15%) | PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- VIL1 | c.568-1G>A p.X190_splice | Splice Site (SNP) | VAF 52/271 reads (19%) | called by muse, mutect2, varscan2
- XRCC4 | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 51/263 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ZC3H11A | c.1573G>T p.E525* | Nonsense Mutation (SNP) | VAF 42/255 reads (16%) | called by muse, mutect2, varscan2
- ZNF14 | c.13T>A p.S5T | Missense Mutation (SNP) | VAF 51/289 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF20 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 55/302 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- ZNF200 | c.373C>T p.H125Y | Missense Mutation (SNP) | VAF 40/211 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- ZNF208 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 90/463 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- ZNF717 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 23/380 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- ZNF804A | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 64/380 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- ZXDA | c.1538C>T p.P513L | Missense Mutation (SNP) | VAF 117/714 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ABCA4 | c.5238C>T p.F1746= | Silent (SNP) | VAF 76/386 reads (20%) | catalogued as COSV64673738; called by muse, varscan2
- ACVR1C | c.726C>T p.V242= | Silent (SNP) | VAF 49/400 reads (12%) | called by muse, mutect2, varscan2
- ADAM11 | c.591C>T p.P197= | Silent (SNP) | VAF 68/375 reads (18%) | called by muse, mutect2, varscan2
- ADAM29 | c.789G>A p.R263= | Silent (SNP) | VAF 72/408 reads (18%) | catalogued as COSV63668058; called by muse, mutect2, varscan2
- ADCY8 | c.2448G>A p.K816= | Silent (SNP) | VAF 53/298 reads (18%) | called by muse, mutect2, varscan2
- ADGRV1 | c.4455C>T p.S1485= | Silent (SNP) | VAF 53/335 reads (16%) | called by muse, mutect2, varscan2
- AFF3 | c.1974C>T p.I658= | Silent (SNP) | VAF 76/446 reads (17%) | catalogued as rs1331785768, COSV57877189; called by muse, mutect2, varscan2
- ANK1 | c.5493G>A p.V1831= | Silent (SNP) | VAF 52/294 reads (18%) | catalogued as rs765580346; called by muse, varscan2
- ATP10A | c.921C>T p.N307= | Silent (SNP) | VAF 78/396 reads (20%) | catalogued as rs1272430142, COSV63520794; called by muse, mutect2, varscan2
- ATP4A | c.117G>A p.R39= | Silent (SNP) | VAF 75/331 reads (23%) | called by muse, mutect2, varscan2
- ATPAF2 | c.528C>T p.S176= | Silent (SNP) | VAF 48/294 reads (16%) | called by muse, mutect2, varscan2
- BSN | c.3882G>A p.E1294= | Silent (SNP) | VAF 72/539 reads (13%) | called by muse, mutect2, varscan2
- C6 | c.1938G>A p.Q646= | Silent (SNP) | VAF 58/316 reads (18%) | called by muse, mutect2, varscan2
- CACNA1B | c.5178G>A p.L1726= | Silent (SNP) | VAF 136/346 reads (39%) | catalogued as COSV53133119; called by muse, mutect2, varscan2
- CACNG3 | c.804C>T p.S268= | Silent (SNP) | VAF 70/545 reads (13%) | catalogued as rs1027898569, COSV50065965; called by muse, mutect2, varscan2
- CCDC157 | c.1488G>A p.Q496= | Silent (SNP) | VAF 58/392 reads (15%) | called by muse, mutect2, varscan2
- CCDC175 | c.1827A>G p.R609= | Silent (SNP) | VAF 41/180 reads (23%) | called by muse, mutect2, varscan2
- CCDC22 | c.546G>A p.E182= | Silent (SNP) | VAF 83/517 reads (16%) | catalogued as COSV66109458; called by muse, mutect2, varscan2
- CCDC60 | c.408C>T p.I136= | Silent (SNP) | VAF 57/316 reads (18%) | catalogued as rs762470910; called by muse, mutect2, varscan2
- CCT8L2 | c.654C>A p.L218= | Silent (SNP) | VAF 91/523 reads (17%) | catalogued as COSV63463864; called by muse, mutect2, varscan2
- CD300LG | c.465C>T p.T155= | Silent (SNP) | VAF 68/424 reads (16%) | called by muse, mutect2, varscan2
- CDH10 | c.807C>T p.F269= | Silent (SNP) | VAF 64/317 reads (20%) | catalogued as COSV100051552, COSV52568750; called by muse, mutect2, varscan2
- CDH22 | c.1140C>T p.I380= | Silent (SNP) | VAF 98/627 reads (16%) | catalogued as rs1429366813, COSV64836477; called by muse, mutect2, varscan2
- CHD6 | c.4113G>A p.K1371= | Silent (SNP) | VAF 57/328 reads (17%) | called by muse, mutect2, varscan2
- CNGA1 | c.987C>T p.V329= | Silent (SNP) | VAF 61/357 reads (17%) | called by muse, mutect2, varscan2
- CNGA2 | c.1956G>A p.G652= | Silent (SNP) | VAF 68/452 reads (15%) | catalogued as rs1236493662, COSV61706290; called by muse, mutect2, varscan2
- CNTN3 | c.111C>T p.F37= | Silent (SNP) | VAF 41/277 reads (15%) | catalogued as COSV55163885; called by muse, mutect2, varscan2
- CPA5 | c.660C>T p.D220= | Silent (SNP) | VAF 210/453 reads (46%) | called by muse, mutect2, varscan2
- CXorf58 | c.279G>A p.K93= | Silent (SNP) | VAF 59/313 reads (19%) | called by muse, mutect2, varscan2
- CYFIP2 | c.3105G>A p.E1035= (on ENST00000616178 / NM_001291722.2; = p.E1010= on NM_014376.4) | Silent (SNP) | VAF 41/228 reads (18%) | called by muse, mutect2, varscan2
- CYLC2 | c.558G>A p.K186= | Silent (SNP) | VAF 92/406 reads (23%) | catalogued as rs1564097820, COSV66336958; called by muse, mutect2, varscan2
- CYP4B1 | c.138C>T p.F46= | Silent (SNP) | VAF 79/395 reads (20%) | catalogued as COSV54726107; called by muse, mutect2, varscan2
- DNAH5 | c.6885G>A p.A2295= | Silent (SNP) | VAF 72/401 reads (18%) | catalogued as rs762437869, COSV54242772, COSV99443106; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAH7 | c.5445C>T p.S1815= | Silent (SNP) | VAF 48/279 reads (17%) | called by muse, mutect2, varscan2
- DSCAM | c.3270C>T p.Y1090= | Silent (SNP) | VAF 28/250 reads (11%) | catalogued as COSV68021736; called by muse, mutect2, varscan2
- DUOX2 | c.4116G>A p.Q1372= | Silent (SNP) | VAF 86/483 reads (18%) | called by muse, mutect2, varscan2
- DYNC2H1 | c.12072C>T p.S4024= | Silent (SNP) | VAF 38/243 reads (16%) | called by muse, mutect2
- ECHDC1 | c.105C>T p.S35= (on ENST00000531967 / NM_001139510.1; = p.S29= on NM_018479.3) | Silent (SNP) | VAF 59/458 reads (13%) | called by muse, mutect2, varscan2
- EIF3E | c.1041C>T p.I347= | Silent (SNP) | VAF 54/306 reads (18%) | called by muse, mutect2, varscan2
- EIF4G3 | c.21C>T p.T7= | Silent (SNP) | VAF 80/483 reads (17%) | called by muse, mutect2, varscan2
- ELMO3 | c.1476C>T p.F492= (on ENST00000652269; = p.F439= on NM_024712.5) | Silent (SNP) | VAF 75/473 reads (16%) | called by muse, mutect2, varscan2
- EML1 | c.2376C>T p.F792= | Silent (SNP) | VAF 58/416 reads (14%) | catalogued as rs1377216398; called by muse, mutect2, varscan2
- EML6 | c.1767C>T p.F589= | Silent (SNP) | VAF 53/359 reads (15%) | catalogued as rs1194029370; called by muse, mutect2, varscan2
- EPS8L3 | c.273C>T p.Y91= | Silent (SNP) | VAF 43/306 reads (14%) | called by muse, mutect2, varscan2
- FAAH | c.909C>T p.F303= | Silent (SNP) | VAF 79/422 reads (19%) | called by muse, mutect2, varscan2
- FAM151A | c.84C>T p.A28= | Silent (SNP) | VAF 56/372 reads (15%) | catalogued as rs188902293, COSV100157018; called by muse, mutect2, varscan2
- FAM83B | c.1377G>A p.R459= | Silent (SNP) | VAF 96/453 reads (21%) | catalogued as COSV60921971, COSV60925896; called by muse, mutect2, varscan2
- FAM83E | c.1324C>T p.L442= | Silent (SNP) | VAF 70/515 reads (14%) | called by muse, mutect2, varscan2
- FFAR3 | c.294C>T p.T98= | Silent (SNP) | VAF 47/594 reads (8%) | called by muse, mutect2
- FLNA | c.2868C>T p.I956= | Silent (SNP) | VAF 70/434 reads (16%) | called by muse, mutect2, varscan2
- FREM3 | c.5796G>A p.T1932= | Silent (SNP) | VAF 45/260 reads (17%) | catalogued as rs1319410474, COSV61679089; called by muse, mutect2, varscan2
- FURIN | c.1509C>T p.I503= | Silent (SNP) | VAF 84/446 reads (19%) | catalogued as rs1180335465; called by muse, mutect2, varscan2
- GALNT13 | c.786G>A p.L262= | Silent (SNP) | VAF 38/355 reads (11%) | catalogued as COSV67227808; called by muse, mutect2, varscan2
- GIGYF1 | c.195C>T p.F65= | Silent (SNP) | VAF 384/715 reads (54%) | catalogued as rs748189110, COSV51945578; called by muse, mutect2, varscan2
- GSTM5 | c.612C>T p.L204= | Silent (SNP) | VAF 44/302 reads (15%) | called by muse, mutect2, varscan2
- GYG1 | c.64C>T p.L22= | Silent (SNP) | VAF 78/449 reads (17%) | called by muse, mutect2, varscan2
- HADHB | c.126G>A p.T42= | Silent (SNP) | VAF 51/299 reads (17%) | catalogued as rs1475892789, COSV58545899; called by muse, mutect2, varscan2
- HHATL | c.876C>T p.A292= | Silent (SNP) | VAF 52/271 reads (19%) | catalogued as COSV55133926; called by muse, mutect2, varscan2
- HK3 | c.1362C>T p.S454= | Silent (SNP) | VAF 86/469 reads (18%) | catalogued as rs747900803; called by muse, mutect2, varscan2
- HMGCS2 | c.273C>T p.T91= | Silent (SNP) | VAF 88/497 reads (18%) | called by muse, mutect2, varscan2
- HNRNPL | c.1098C>T p.P366= | Silent (SNP) | VAF 58/374 reads (16%) | called by muse, varscan2
- HSP90AA1 | c.1935C>T p.T645= | Silent (SNP) | VAF 59/355 reads (17%) | catalogued as rs780775524, COSV53490114; called by muse, mutect2, varscan2
- IFNAR1 | c.1359C>T p.V453= | Silent (SNP) | VAF 55/302 reads (18%) | called by muse, mutect2, varscan2
- IGHMBP2 | c.1983C>T p.H661= | Silent (SNP) | VAF 64/442 reads (14%) | catalogued as rs752907111, COSV54819994; called by muse, varscan2
- IGKV3-15 | c.126C>T p.S42= | Silent (SNP) | VAF 46/644 reads (7%) | catalogued as rs1399538383; called by muse, mutect2
- IGSF9 | c.2283C>T p.N761= (on ENST00000368094 / NM_001135050.2; = p.N745= on NM_020789.4) | Silent (SNP) | VAF 142/640 reads (22%) | called by muse, mutect2, varscan2
- IL1B | c.132G>A p.L44= | Silent (SNP) | VAF 48/341 reads (14%) | called by muse, mutect2, varscan2
- IL1RL2 | c.765G>A p.K255= | Silent (SNP) | VAF 48/286 reads (17%) | catalogued as rs1416191438, COSV51818761; called by muse, mutect2, varscan2
- ILDR1 | c.495C>T p.V165= | Silent (SNP) | VAF 31/176 reads (18%) | called by muse, mutect2, varscan2
- KCNA1 | c.45C>T p.A15= | Silent (SNP) | VAF 96/458 reads (21%) | called by muse, mutect2, varscan2
- LEAP2 | c.36C>T p.I12= | Silent (SNP) | VAF 60/433 reads (14%) | catalogued as rs777659169; called by muse, mutect2, varscan2
- LILRA1 | c.777G>A p.K259= | Silent (SNP) | VAF 102/674 reads (15%) | catalogued as COSV52185350; called by muse, mutect2, varscan2
- LOXL1 | c.1510C>T p.L504= | Silent (SNP) | VAF 51/304 reads (17%) | called by muse, mutect2, varscan2
- LRRTM3 | c.1056C>T p.I352= | Silent (SNP) | VAF 70/415 reads (17%) | called by muse, mutect2, varscan2
- MAGEC3 | c.933C>T p.F311= | Silent (SNP) | VAF 50/308 reads (16%) | catalogued as rs146271957, COSV53577041, COSV53579199; called by muse, mutect2, varscan2
- MALRD1 | c.4512C>T p.F1504= | Silent (SNP) | VAF 67/379 reads (18%) | catalogued as rs1433882411; called by muse, mutect2, varscan2
- MAP3K4 | c.1848C>T p.F616= | Silent (SNP) | VAF 77/358 reads (22%) | catalogued as COSV62333361; called by muse, mutect2, varscan2
- MARS1 | c.2400C>T p.P800= | Silent (SNP) | VAF 39/259 reads (15%) | catalogued as COSV56255023; called by muse, mutect2, varscan2
- MED12L | c.2472C>T p.L824= | Silent (SNP) | VAF 91/483 reads (19%) | catalogued as COSV56398351; called by muse, mutect2, varscan2
- MED13L | c.1527G>T p.G509= | Silent (SNP) | VAF 25/601 reads (4%) | called by muse, mutect2
- MORC4 | c.1179C>T p.A393= | Silent (SNP) | VAF 44/279 reads (16%) | called by muse, mutect2, varscan2
- MORF4L2 | c.429G>A p.Q143= | Silent (SNP) | VAF 97/542 reads (18%) | called by muse, mutect2, varscan2
- MPP4 | c.1671G>A p.R557= | Silent (SNP) | VAF 63/368 reads (17%) | called by muse, mutect2, varscan2
- MRGPRE | c.381C>T p.F127= | Silent (SNP) | VAF 99/639 reads (15%) | called by muse, mutect2, varscan2
- MS4A14 | c.1848C>T p.S616= | Silent (SNP) | VAF 62/424 reads (15%) | catalogued as rs1346480846, COSV100280255; called by muse, mutect2, varscan2
- MTMR10 | c.264C>T p.F88= | Silent (SNP) | VAF 34/213 reads (16%) | called by muse, mutect2, varscan2
- MTRNR2L5 | c.69G>A p.R23= | Silent (SNP) | VAF 35/206 reads (17%) | catalogued as rs1458670166; called by muse, mutect2, varscan2
- MUC17 | c.11649C>A p.T3883= | Silent (SNP) | VAF 34/736 reads (5%) | called by muse, mutect2
- MYCT1 | c.87C>T p.F29= | Silent (SNP) | VAF 42/274 reads (15%) | catalogued as rs568217820, COSV65890898; called by muse, mutect2, varscan2
- NCR3LG1 | c.996G>A p.Q332= | Silent (SNP) | VAF 100/508 reads (20%) | called by muse, mutect2, varscan2
- NEPRO | c.441C>T p.L147= | Silent (SNP) | VAF 59/362 reads (16%) | catalogued as rs1408913110; called by muse, mutect2, varscan2
- NGEF | c.1218C>T p.S406= | Silent (SNP) | VAF 58/344 reads (17%) | catalogued as COSV50919194; called by muse, mutect2, varscan2
- NLRP11 | c.1548G>A p.P516= | Silent (SNP) | VAF 47/363 reads (13%) | catalogued as rs757674862, COSV100789821; called by muse, mutect2, varscan2
- NME1-NME2 | c.753G>A p.Q251= (on ENST00000555572; = p.Q226= on NM_001018136.3) | Silent (SNP) | VAF 39/254 reads (15%) | called by muse, mutect2, varscan2
- NMS | c.384G>A p.A128= | Silent (SNP) | VAF 54/333 reads (16%) | catalogued as rs532961780, COSV65258416, COSV65258515; called by muse, mutect2, varscan2
- NOLC1 | c.1992C>T p.F664= | Silent (SNP) | VAF 67/412 reads (16%) | catalogued as COSV64180177; called by muse, mutect2, varscan2
- NOTCH4 | c.3603G>A p.G1201= | Silent (SNP) | VAF 355/1046 reads (34%) | called by muse, mutect2, varscan2
- NUDT8 | c.366C>T p.G122= | Silent (SNP) | VAF 67/387 reads (17%) | catalogued as rs1238380816; called by muse, mutect2, varscan2
- OGDHL | c.1593G>A p.L531= | Silent (SNP) | VAF 80/393 reads (20%) | called by muse, mutect2, varscan2
- OPA3 | c.483C>T p.A161= | Silent (SNP) | VAF 94/544 reads (17%) | called by muse, mutect2, varscan2
- OR1D5 | c.789C>T p.L263= | Silent (SNP) | VAF 42/518 reads (8%) | called by muse, mutect2
- OR51G2 | c.909G>A p.Q303= | Silent (SNP) | VAF 59/371 reads (16%) | catalogued as rs1479455659, COSV58993836; called by muse, mutect2, varscan2
- OR52W1 | c.822C>T p.V274= | Silent (SNP) | VAF 51/324 reads (16%) | called by muse, mutect2, varscan2
- OR5P2 | c.9C>T p.S3= | Silent (SNP) | VAF 29/277 reads (10%) | called by muse, mutect2, varscan2
- OR7E24 | c.121C>T p.L41= | Silent (SNP) | VAF 58/345 reads (17%) | called by muse, mutect2, varscan2
- OR8B2 | c.735C>T p.V245= | Silent (SNP) | VAF 46/338 reads (14%) | called by muse, mutect2, varscan2
- OR9Q1 | c.666C>T p.I222= | Silent (SNP) | VAF 61/440 reads (14%) | catalogued as rs139135884, COSV59038731, COSV59040427; called by muse, mutect2, varscan2
- OSMR | c.2745G>A p.L915= | Silent (SNP) | VAF 54/368 reads (15%) | called by muse, varscan2
- PATE4 | c.45C>T p.L15= | Silent (SNP) | VAF 59/332 reads (18%) | called by muse, mutect2, varscan2
- PCDHB14 | c.1125T>C p.S375= | Silent (SNP) | VAF 48/343 reads (14%) | called by muse, mutect2, varscan2
- PCSK7 | c.1509C>T p.P503= | Silent (SNP) | VAF 47/321 reads (15%) | called by muse, mutect2, varscan2
- PDLIM1 | c.981C>T p.F327= | Silent (SNP) | VAF 39/250 reads (16%) | catalogued as COSV61474654; called by muse, mutect2, varscan2
- PGAP4 | c.57C>T p.S19= | Silent (SNP) | VAF 77/458 reads (17%) | called by muse, mutect2, varscan2
- PLB1 | c.3015G>A p.Q1005= | Silent (SNP) | VAF 71/395 reads (18%) | catalogued as COSV59835082; called by muse, mutect2, varscan2
- PLB1 | c.3702G>A p.Q1234= | Silent (SNP) | VAF 68/406 reads (17%) | called by muse, mutect2, varscan2
- PLK1 | c.237C>T p.F79= | Silent (SNP) | VAF 58/429 reads (14%) | called by muse, mutect2, varscan2
- PLXNB1 | c.2592C>T p.S864= | Silent (SNP) | VAF 93/581 reads (16%) | called by muse, mutect2, varscan2
- POMT2 | c.1965C>T p.F655= | Silent (SNP) | VAF 83/475 reads (17%) | catalogued as COSV99836644; called by muse, mutect2, varscan2
- POTEA | c.1383C>T p.I461= (on ENST00000519951 / NM_001005365.2; = p.I415= on NM_001002920.1) | Silent (SNP) | VAF 46/265 reads (17%) | called by muse, mutect2, varscan2
- PRM1 | c.36G>A p.R12= | Silent (SNP) | VAF 42/310 reads (14%) | catalogued as COSV54113308; called by muse, mutect2, varscan2
- PRPF6 | c.969G>A p.G323= | Silent (SNP) | VAF 66/466 reads (14%) | called by muse, mutect2, varscan2
- PRTG | c.1551C>T p.P517= | Silent (SNP) | VAF 32/244 reads (13%) | called by muse, mutect2, varscan2
- PSG8 | c.1023C>T p.F341= | Silent (SNP) | VAF 42/288 reads (15%) | catalogued as rs1339309377; called by muse, mutect2, varscan2
- PTGFR | c.225C>T p.I75= | Silent (SNP) | VAF 94/515 reads (18%) | catalogued as COSV66115728; called by muse, mutect2, varscan2
- RAD17 | c.552C>T p.F184= (on ENST00000380774 / NM_133339.2; = p.F173= on NM_002873.1) | Silent (SNP) | VAF 21/188 reads (11%) | called by muse, mutect2, varscan2
- REV1 | c.1737C>T p.I579= | Silent (SNP) | VAF 48/371 reads (13%) | called by muse, mutect2, varscan2
- RTL1 | c.2322C>T p.T774= | Silent (SNP) | VAF 97/488 reads (20%) | catalogued as rs553438230, COSV66016430; called by muse, mutect2, varscan2
- SALL1 | c.1953C>T p.P651= | Silent (SNP) | VAF 76/514 reads (15%) | catalogued as rs147169088; called by muse, mutect2, varscan2
- SCARB2 | c.666C>T p.Y222= | Silent (SNP) | VAF 23/219 reads (11%) | called by muse, mutect2, varscan2
- SCD5 | c.180C>T p.A60= | Silent (SNP) | VAF 55/472 reads (12%) | catalogued as rs1381818821; called by muse, mutect2, varscan2
- SCN10A | c.2904G>A p.R968= | Silent (SNP) | VAF 70/476 reads (15%) | catalogued as rs1000594432, COSV101479483; called by muse, mutect2, varscan2
- SENP6 | c.2844C>T p.F948= | Silent (SNP) | VAF 51/369 reads (14%) | called by muse, mutect2, varscan2
- SENP7 | c.220C>T p.L74= | Silent (SNP) | VAF 40/208 reads (19%) | called by muse, mutect2, varscan2
- SEZ6 | c.84G>A p.G28= | Silent (SNP) | VAF 74/407 reads (18%) | catalogued as COSV100253492; called by muse, mutect2, varscan2
- SIGLEC12 | c.918G>A p.T306= (on ENST00000291707 / NM_053003.4; = p.T188= on NM_033329.2) | Silent (SNP) | VAF 94/558 reads (17%) | catalogued as rs375071831; called by muse, mutect2, varscan2
- SLC12A3 | c.885C>T p.V295= | Silent (SNP) | VAF 46/348 reads (13%) | called by muse, mutect2, varscan2
- SLC35C1 | c.711C>T p.N237= | Silent (SNP) | VAF 90/457 reads (20%) | catalogued as rs777163801; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC38A9 | c.462C>T p.I154= | Silent (SNP) | VAF 40/213 reads (19%) | called by muse, mutect2, varscan2
- SLC5A6 | c.1323C>T p.L441= | Silent (SNP) | VAF 67/363 reads (18%) | catalogued as COSV100143207; called by muse, mutect2, varscan2
- SLCO1C1 | c.1068C>T p.F356= | Silent (SNP) | VAF 43/302 reads (14%) | catalogued as rs1455487479, COSV56881734; called by muse, mutect2, varscan2
- SLX4 | c.4701C>T p.S1567= | Silent (SNP) | VAF 68/405 reads (17%) | catalogued as COSV53568582; called by muse, mutect2, varscan2
- SMOC1 | c.231G>A p.P77= | Silent (SNP) | VAF 63/354 reads (18%) | catalogued as rs752850206, COSV62761034; called by muse, mutect2, varscan2
- SOGA3 | c.444G>A p.R148= | Silent (SNP) | VAF 38/591 reads (6%) | called by muse, mutect2
- SPEG | c.8442C>T p.P2814= | Silent (SNP) | VAF 84/409 reads (21%) | catalogued as rs371097046; called by muse, mutect2, varscan2
- SPOCK3 | c.723C>T p.F241= | Silent (SNP) | VAF 37/236 reads (16%) | catalogued as rs1482458459, COSV62739260; called by muse, mutect2, varscan2
- SVOPL | c.384C>T p.S128= | Silent (SNP) | VAF 259/502 reads (52%) | called by muse, mutect2, varscan2
- TNN | c.1845C>T p.N615= | Silent (SNP) | VAF 141/318 reads (44%) | catalogued as rs564187493, COSV53437634; called by muse, mutect2, varscan2
- TNS4 | c.699C>T p.I233= | Silent (SNP) | VAF 92/563 reads (16%) | catalogued as COSV54188675; called by muse, mutect2, varscan2
- TRAF3IP1 | c.2067G>A p.S689= | Silent (SNP) | VAF 29/180 reads (16%) | catalogued as rs897164078; called by muse, mutect2, varscan2
- TRAM2 | c.289T>C p.L97= | Silent (SNP) | VAF 41/281 reads (15%) | called by muse, mutect2, varscan2
- TRPS1 | c.3480T>C p.N1160= (on ENST00000220888 / NM_001330599.2; = p.N1173= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 82/529 reads (16%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.1041G>A p.K347= | Silent (SNP) | VAF 46/315 reads (15%) | called by muse, mutect2, varscan2
- UNC13C | c.6405C>T p.L2135= | Silent (SNP) | VAF 64/342 reads (19%) | catalogued as COSV52840051, COSV99515543; called by muse, mutect2, varscan2
- URB1 | c.2856C>T p.P952= | Silent (SNP) | VAF 60/434 reads (14%) | catalogued as rs1009295615; called by muse, mutect2, varscan2
- VTN | c.819C>T p.F273= | Silent (SNP) | VAF 42/278 reads (15%) | catalogued as COSV56872311; called by muse, mutect2, varscan2
- WDFY4 | c.4002G>A p.R1334= | Silent (SNP) | VAF 68/393 reads (17%) | called by muse, mutect2, varscan2
- XYLT1 | c.2181C>T p.I727= | Silent (SNP) | VAF 72/381 reads (19%) | catalogued as rs112238716; called by muse, mutect2, varscan2
- ZFP42 | c.333C>T p.F111= | Silent (SNP) | VAF 64/380 reads (17%) | catalogued as rs1047170442, COSV58816461; called by muse, mutect2, varscan2
- ZFYVE26 | c.6582C>T p.L2194= | Silent (SNP) | VAF 82/539 reads (15%) | catalogued as rs1187035716; called by muse, mutect2, varscan2
- ZIC1 | c.396C>T p.H132= | Silent (SNP) | VAF 101/575 reads (18%) | catalogued as rs1202675506, COSV51551314; called by muse, mutect2, varscan2
- ZNF277 | c.1071C>T p.C357= | Silent (SNP) | VAF 337/635 reads (53%) | called by muse, mutect2, varscan2
- ZNF629 | c.1542C>T p.F514= | Silent (SNP) | VAF 79/519 reads (15%) | catalogued as COSV52700901; called by muse, mutect2, varscan2
- ZNF777 | c.639G>A p.T213= | Silent (SNP) | VAF 367/694 reads (53%) | catalogued as rs199585345, COSV99925107; called by muse, varscan2
- ZZEF1 | c.5037A>T p.T1679= | Silent (SNP) | VAF 33/316 reads (10%) | called by muse, mutect2, varscan2
- AL031848.2 | chr1:6393350 C>G | 5'Flank (SNP) | VAF 44/393 reads (11%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73821907 G>A | 5'Flank (SNP) | VAF 46/282 reads (16%) | called by muse, mutect2, varscan2
- BBS1 | c.1340-392C>T | Intron (SNP) | VAF 70/430 reads (16%) | catalogued as rs1225985416; called by muse, mutect2, varscan2
- CCKBR | c.811+71G>A | Intron (SNP) | VAF 87/512 reads (17%) | called by muse, mutect2, varscan2
- EEF1D | c.-7-2640C>T | Intron (SNP) | VAF 108/615 reads (18%) | called by muse, mutect2, varscan2
- GUCY1B1 | c.298-4397C>A | Intron (SNP) | VAF 20/224 reads (9%) | called by muse, mutect2
- KCNQ1 | c.1394-16592G>A | Intron (SNP) | VAF 43/297 reads (14%) | catalogued as rs1435540504; called by muse, mutect2, varscan2
